Somatic mutation profile of tumor specimen TCGA-HT-7688-01A (aliquot TCGA-HT-7688-01A-11D-2253-08) from TCGA case TCGA-HT-7688, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 59.8 years (21,844 days).
Specimen TCGA-HT-7688-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e9fbdb5-a9e3-4216-a837-5285f64ec22d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7688-10A (Blood Derived Normal), aliquot TCGA-HT-7688-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/396af906-e4a6-4f2d-addf-1ab6e0381064

The open-access MAF lists 80 somatic variants for this specimen: 64 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 14, Frame Shift Del 10, In Frame Del 4, Intron 2, Nonsense Mutation 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/93 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SMARCA4 | c.1636_1638del p.K546del | In Frame Del (DEL) | VAF 24/151 reads (16%) | hotspot (GDC flag); catalogued as rs876657378; called by pindel, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 60/108 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.4259A>G p.K1420R | Missense Mutation (SNP) | VAF 157/510 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52636380; called by muse, mutect2, varscan2
- AGL | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV54048769; called by muse, mutect2, varscan2
- APOBEC3F | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1316507478, COSV57911498; called by muse, mutect2, varscan2
- ARID1A | c.3977del p.P1326Rfs*155 | Frame Shift Del (DEL) | VAF 16/119 reads (13%) | catalogued as COSV61372705; called by mutect2, pindel, varscan2
- ARID1B | c.4606C>G p.H1536D | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51651184; called by muse, mutect2
- ARMH4 | c.103_105del p.R35del | In Frame Del (DEL) | VAF 35/122 reads (29%) | catalogued as rs749502324; called by pindel, varscan2
- CAD | c.5391del p.Q1798Rfs*33 | Frame Shift Del (DEL) | VAF 19/84 reads (23%) | catalogued as COSV99254654; called by mutect2, pindel, varscan2
- CCR7 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV55848725; called by muse, mutect2
- CD1E | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs142840776, COSV63770226; called by muse, varscan2
- CLIP1 | c.3646del p.R1216Efs*6 (on ENST00000620786 / NM_001247997.1; = p.R1205Efs*6 on NM_002956.2) | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs761972338; called by mutect2, pindel, varscan2
- CPXM2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749545644, COSV53857243; called by muse, mutect2, varscan2
- CYP4F22 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs146265982, COSV54106998; called by muse, mutect2, varscan2
- CYP4Z1 | c.21G>C p.Q7H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.288); catalogued as rs767665833, COSV61963989; called by muse, mutect2
- EIF2AK3 | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.985); catalogued as COSV57545444; called by muse, mutect2
- FLG2 | c.6749G>C p.R2250T | Missense Mutation (SNP) | VAF 20/814 reads (2%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); catalogued as COSV66167054; called by muse, mutect2
- FMR1NB | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0.013); catalogued as COSV100789540, COSV63272692; called by muse, mutect2, varscan2
- HOXC4 | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57698052; called by muse, mutect2, varscan2
- IL6 | c.380A>T p.E127V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV51732386; called by muse, mutect2, varscan2
- INTS9 | c.1825G>C p.E609Q | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as COSV68433335; called by muse, mutect2
- KRI1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); catalogued as rs775024147, COSV57263794; called by muse, mutect2, varscan2
- KRT33A | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs750904301, COSV50365705; called by muse, mutect2
- MAP1B | c.4429A>G p.K1477E | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV57094870; called by muse, mutect2, varscan2
- MBL2 | c.163A>G p.T55A | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as rs886047053, COSV64758090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MC4R | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs758426526, CM035970, COSV55351515; called by muse, mutect2, varscan2
- MKI67 | c.69C>G p.S23R | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV64072985; called by muse, mutect2
- MROH9 | c.275T>C p.I92T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV63010239; called by muse, mutect2, varscan2
- MSL3 | c.1171+6T>C | Splice Region (SNP) | VAF 23/147 reads (16%) | catalogued as COSV100384614; called by muse, mutect2, varscan2
- MYO3A | c.4095G>T p.Q1365H | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV56322036; called by muse, mutect2, varscan2
- OR2M7 | c.906G>T p.M302I | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58738172, COSV58738358; called by muse, mutect2, varscan2
- OSBP2 | c.729C>G p.I243M | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV60240349; called by muse, mutect2
- PCNX1 | c.3304A>C p.I1102L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53090461; called by muse, mutect2
- PI15 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 10/318 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.11); catalogued as COSV52639533, COSV52640021; called by muse, mutect2
- PRDM1 | c.1256G>A p.G419D | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as COSV64844596; called by muse, mutect2, varscan2
- PTPRR | c.1832_1834del p.E611del | In Frame Del (DEL) | VAF 34/164 reads (21%) | catalogued as rs1566047087; called by pindel, varscan2
- RLF | c.1993C>G p.L665V | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV65650882; called by muse, mutect2, varscan2
- RORB | c.571C>T p.Q191* (on ENST00000396204 / NM_001365023.1; = p.Q180* on NM_006914.4) | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as COSV65333392; called by muse, mutect2, varscan2
- SCYL3 | c.2048T>C p.I683T (on ENST00000367770; = p.I629T on NM_020423.7) | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53677084, COSV53677964; called by muse, mutect2
- SEMA6D | c.123T>A p.Y41* | Nonsense Mutation (SNP) | VAF 4/67 reads (6%) | catalogued as COSV60373544; called by muse, mutect2
- SEPTIN4 | c.1319G>A p.S440N | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.042); catalogued as COSV58727266; called by muse, mutect2, varscan2
- SLC26A11 | c.515A>G p.N172S | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV63279003; called by muse, mutect2, varscan2
- SNRNP40 | c.707A>G p.D236G | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55276481; called by muse, mutect2, varscan2
- SUPT16H | c.362T>C p.M121T | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs1450658265, COSV53522686; called by muse, mutect2
- SYCP1 | c.2019A>G p.I673M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV65695031; called by muse, mutect2
- TAS1R2 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as rs1476026047, COSV64743851; called by muse, mutect2, varscan2
- TGM6 | c.1769T>C p.V590A | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as COSV52477825; called by muse, mutect2
- TMCC1 | c.35A>C p.D12A | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); catalogued as COSV67872466; called by muse, mutect2
- TMEM175 | c.277G>C p.A93P | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); catalogued as COSV53277776; called by muse, mutect2
- TNFRSF12A | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV99560452; called by muse, mutect2, varscan2
- TPX2 | c.2134-1G>C p.X712_splice | Splice Site (SNP) | VAF 10/188 reads (5%) | catalogued as COSV55917924; called by muse, mutect2
- TREML2 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as COSV72439038; called by muse, mutect2, varscan2
- UTY | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.874); catalogued as COSV58868413; called by muse, mutect2, varscan2
- ZNF17 | c.1748A>G p.K583R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV56920867; called by muse, mutect2, varscan2
- ZSWIM8 | c.3801_3802del p.G1269Pfs*69 (on ENST00000605216 / NM_001242487.2; = p.G1274Pfs*69 on NM_015037.3) | Frame Shift Del (DEL) | VAF 25/216 reads (12%) | catalogued as rs779171507; called by mutect2, pindel, varscan2
- ARID5B | c.1272del p.K424Nfs*55 | Frame Shift Del (DEL) | VAF 45/143 reads (31%) | called by mutect2, pindel, varscan2
- ATRX | c.5272+2_5272+3del p.X1758_splice | Splice Site (DEL) | VAF 8/36 reads (22%) | called by pindel, varscan2
- CDON | c.255_256del p.L87Qfs*15 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | called by mutect2, pindel, varscan2
- EPB41L2 | c.838_841del p.K280Dfs*3 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- ESCO1 | c.546_550del p.K183* | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel
- FBN2 | c.923_926del p.K308Rfs*42 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- HIRA | c.942_943del p.C315Sfs*10 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel, varscan2
- NCOA4 | c.1128_1130del p.K377del | In Frame Del (DEL) | VAF 16/36 reads (44%) | called by mutect2, pindel, varscan2
- ARHGEF35 | c.1140G>A p.E380= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as COSV65312440; called by muse, varscan2
- COL20A1 | c.3828G>A p.G1276= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV58912722; called by muse, mutect2
- GATM | c.891A>G p.K297= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV67540199; called by muse, mutect2, varscan2
- GRB10 | c.675A>G p.E225= | Silent (SNP) | VAF 8/149 reads (5%) | catalogued as COSV60007933; called by muse, mutect2
- LVRN | c.331C>T p.L111= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as COSV63496401; called by muse, mutect2, varscan2
- NCKAP1L | c.1944G>A p.R648= | Silent (SNP) | VAF 6/113 reads (5%) | catalogued as COSV53204085; called by muse, mutect2
- NPHS1 | c.795C>T p.C265= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs779099247, COSV62286668; called by muse, mutect2, varscan2
- PTPN4 | c.1788A>G p.E596= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV55298369; called by muse, mutect2
- SIPA1L3 | c.3570T>C p.D1190= | Silent (SNP) | VAF 49/240 reads (20%) | catalogued as COSV55909818; called by muse, mutect2, varscan2
- SORL1 | c.2745G>C p.L915= | Silent (SNP) | VAF 8/246 reads (3%) | catalogued as COSV52750378; called by muse, mutect2
- TG | c.3360G>A p.S1120= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs1357840489, COSV55067198; called by muse, mutect2
- TRIM9 | c.1965A>G p.R655= | Silent (SNP) | VAF 14/257 reads (5%) | catalogued as COSV53613593; called by muse, mutect2
- TTN | c.51633C>T p.G17211= (on ENST00000591111; = p.G9787= on NM_003319.4) | Silent (SNP) | VAF 29/160 reads (18%) | catalogued as COSV59916206; called by muse, mutect2, varscan2
- ZNF207 | c.1350G>A p.P450= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as rs1306620482, COSV58299030; called by muse, mutect2
- GBA3 | c.59-8350T>C | Intron (SNP) | VAF 59/195 reads (30%) | called by muse, mutect2, varscan2
- OBSCN | c.11660-2010G>A | Intron (SNP) | VAF 8/178 reads (4%) | catalogued as COSV99474626; called by muse, mutect2
